Somatic mutation profile of tumor specimen TCGA-YA-A8S7-01A (aliquot TCGA-YA-A8S7-01A-11D-A36X-10) from TCGA case TCGA-YA-A8S7, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 69.0 years (25,188 days).
Specimen TCGA-YA-A8S7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98fd4ea5-7fde-421e-bbf7-7d44fa34dde1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YA-A8S7-10A (Blood Derived Normal), aliquot TCGA-YA-A8S7-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b73ea164-6fcc-4434-b455-7bb9c14e6b49

The open-access MAF lists 79 somatic variants for this specimen: 57 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 21, Frame Shift Del 4, Frame Shift Ins 2, RNA 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CANT1 | c.392A>G p.K131R | Missense Mutation (SNP) | VAF 4/54 reads (7%) | hotspot (GDC flag); SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV56605000; called by muse, mutect2
- TP53 | c.614A>C p.Y205S | Missense Mutation (SNP) | VAF 52/145 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs1057520007, COSV52665440, COSV52677268, COSV52688506; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAM2 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.231); catalogued as rs765528383, COSV55862854; called by muse, mutect2, varscan2
- ADCY9 | c.3858G>T p.Q1286H | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs370863551, COSV99570028; called by muse, mutect2, varscan2
- AHNAK | c.3103G>T p.D1035Y | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99947543, COSV99947804; called by muse, mutect2, varscan2
- AKTIP | c.314-1G>A p.X105_splice | Splice Site (SNP) | VAF 30/242 reads (12%) | catalogued as COSV100043653; called by muse, mutect2, varscan2
- ANKRD7 | c.686A>C p.N229T | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as COSV99501142; called by muse, mutect2, varscan2
- ARGFX | c.364G>C p.V122L | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.579); catalogued as COSV57682385, COSV57682611; called by muse, mutect2, varscan2
- ARHGAP32 | c.671C>A p.A224D | Missense Mutation (SNP) | VAF 124/448 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV100087916; called by muse, varscan2
- BCAN | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 79/171 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.311); catalogued as rs761137329, COSV100228101; called by muse, mutect2, varscan2
- CCDC60 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778425978, COSV59543287; called by muse, mutect2, varscan2
- CCDC9 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as COSV55720439; called by muse, mutect2, varscan2
- CD300LG | c.651dup p.M218Hfs*21 | Frame Shift Ins (INS) | VAF 11/57 reads (19%) | catalogued as rs760923345; called by mutect2, varscan2
- DLG3 | c.1649C>G p.T550S (on ENST00000374360 / NM_021120.4; = p.T213S on NM_020730.3) | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV99529547; called by muse, mutect2
- DOP1A | c.4076A>G p.N1359S | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs145538359; called by muse, mutect2
- ECT2 | c.138G>C p.M46I | Missense Mutation (SNP) | VAF 71/295 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs776600254, COSV99221371; called by muse, mutect2, varscan2
- EEF1A1 | c.130A>G p.K44E | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.105); catalogued as COSV58549875; called by muse, mutect2, varscan2
- ETFDH | c.1335G>A p.W445* | Nonsense Mutation (SNP) | VAF 28/75 reads (37%) | catalogued as COSV100306832; called by muse, mutect2, varscan2
- FGD6 | c.3400T>G p.S1134A | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.975); catalogued as COSV100676593; called by muse, mutect2, varscan2
- FUT9 | c.661G>C p.A221P | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.518); catalogued as COSV100133651; called by muse, mutect2, varscan2
- GPR65 | c.722C>A p.P241H | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99966055; called by muse, mutect2, varscan2
- HCAR3 | c.50A>T p.N17I | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV100811617; called by muse, mutect2
- IPO4 | c.3208A>C p.K1070Q | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV100269045; called by muse, mutect2
- KANK1 | c.318C>A p.F106L | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.042); catalogued as COSV100619772; called by muse, mutect2, varscan2
- KIR2DL1 | c.665G>A p.G222E | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.149); catalogued as rs113536578, COSV52415400; called by muse, mutect2, varscan2
- LCE1D | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 154/564 reads (27%) | PolyPhen possibly damaging (0.553); catalogued as COSV100405897, COSV58271059; called by muse, mutect2
- LRRIQ3 | c.911G>T p.R304I | Missense Mutation (SNP) | VAF 71/305 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV100598864; called by muse, mutect2, varscan2
- MACROH2A1 | c.1015G>A p.V339M (on ENST00000510038; = p.V338M on NM_004893.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/202 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.834); catalogued as rs149823680; called by muse, mutect2, varscan2
- MAN1A1 | c.1405C>T p.H469Y | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100870637; called by muse, mutect2, varscan2
- MRC2 | c.2540C>T p.A847V | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1260446244, COSV100316265; called by muse, mutect2, varscan2
- NKX2-1 | c.215C>A p.A72E | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.995); catalogued as COSV100701909, COSV61387956; called by muse, mutect2, varscan2
- OR6X1 | c.142T>C p.W48R | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV100020540; called by muse, mutect2, varscan2
- OTOGL | c.6125G>A p.C2042Y (on ENST00000547103; = p.C2033Y on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100087285; called by muse, mutect2, varscan2
- PARP4 | c.3125A>G p.Q1042R | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV101131648; called by muse, mutect2, varscan2
- PITPNM1 | c.1708C>G p.L570V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100711665; called by muse, mutect2, varscan2
- PLEKHM2 | c.1927A>G p.T643A | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101009126; called by muse, mutect2, varscan2
- PPFIA3 | c.3401T>C p.F1134S | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV99417936; called by muse, mutect2, varscan2
- RBM12B | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770059077, COSV101197146; called by muse, mutect2, varscan2
- RYR2 | c.3257G>A p.R1086Q | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as rs749566870, COSV63666545; called by muse, mutect2, varscan2
- SELENOI | c.1147C>A p.P383T | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as COSV99564451; called by muse, mutect2, varscan2
- SF3A2 | c.350A>G p.Y117C | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99677841; called by muse, mutect2, varscan2
- SHKBP1 | c.1751G>A p.G584D | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.047); catalogued as COSV99192659; called by muse, mutect2, varscan2
- SLC6A11 | c.1652A>G p.Y551C | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.886); catalogued as COSV54391089; called by muse, mutect2, varscan2
- SLCO6A1 | c.547C>G p.L183V | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.714); catalogued as COSV101134349, COSV65805451; called by muse, mutect2, varscan2
- SQLE | c.1471T>A p.C491S | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99772333; called by muse, mutect2
- SUSD4 | c.1337C>T p.P446L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV100663763; called by muse, mutect2, varscan2
- USP24 | c.2819A>T p.D940V | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99599763; called by muse, mutect2, varscan2
- XIRP2 | c.7931A>G p.E2644G (on ENST00000628543; = p.E2819G on NM_152381.6) | Missense Mutation (SNP) | VAF 11/258 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99743076; called by muse, mutect2
- ZC3H18 | c.1412A>T p.D471V | Missense Mutation (SNP) | VAF 142/293 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.405); catalogued as COSV99964125; called by muse, mutect2, varscan2
- ZNF479 | c.1008G>C p.W336C | Missense Mutation (SNP) | VAF 81/246 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100482578, COSV100482758, COSV100482804; called by muse, mutect2, varscan2
- ZNF831 | c.1522C>G p.P508A | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100926035; called by muse, mutect2, varscan2
- ZNF831 | c.2750C>G p.P917R | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.216); catalogued as COSV100926036; called by muse, mutect2
- APOB | c.4047dup p.V1350Sfs*45 | Frame Shift Ins (INS) | VAF 24/113 reads (21%) | called by mutect2, pindel, varscan2
- GUCY2D | c.1319del p.G440Dfs*48 | Frame Shift Del (DEL) | VAF 11/34 reads (32%) | called by mutect2, pindel, varscan2
- IP6K1 | c.217del p.Y73Tfs*19 | Frame Shift Del (DEL) | VAF 23/129 reads (18%) | called by mutect2, pindel, varscan2
- NFATC2 | c.2651_2666del p.Q884Lfs*4 | Frame Shift Del (DEL) | VAF 24/124 reads (19%) | called by mutect2, pindel, varscan2
- SNX27 | c.1129del p.V377Lfs*12 | Frame Shift Del (DEL) | VAF 76/185 reads (41%) | called by mutect2, pindel, varscan2
- ADGRL1 | c.606C>A p.T202= (on ENST00000340736 / NM_001008701.3; = p.T197= on NM_014921.5) | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV100529539; called by muse, mutect2, varscan2
- COL12A1 | c.120T>A p.T40= | Silent (SNP) | VAF 36/88 reads (41%) | catalogued as rs1341161177, COSV100486014; called by muse, mutect2, varscan2
- CPED1 | c.2037A>G p.T679= | Silent (SNP) | VAF 47/136 reads (35%) | catalogued as COSV100120763; called by muse, mutect2, varscan2
- CYP7A1 | c.1176G>A p.Q392= | Silent (SNP) | VAF 26/280 reads (9%) | catalogued as rs758271532, COSV100052389; called by muse, mutect2
- DCAF13 | c.36T>C p.N12= | Silent (SNP) | VAF 15/146 reads (10%) | catalogued as COSV99884463; called by muse, mutect2, varscan2
- DCP1B | c.918A>G p.P306= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV99767523; called by muse, mutect2, varscan2
- DNAH7 | c.3724C>T p.L1242= | Silent (SNP) | VAF 85/292 reads (29%) | catalogued as rs1277193304, COSV100415261; called by muse, mutect2, varscan2
- DNAJC13 | c.906A>G p.Q302= | Silent (SNP) | VAF 71/350 reads (20%) | catalogued as COSV53456982; called by muse, mutect2, varscan2
- FRY | c.3225C>T p.L1075= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as rs1488881147, COSV100969302; called by muse, mutect2, varscan2
- GABRA5 | c.510T>G p.S170= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV100165167; called by muse, mutect2, varscan2
- GRK1 | c.783C>A p.A261= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV100175347; called by muse, mutect2, varscan2
- LHPP | c.36C>T p.R12= | Silent (SNP) | VAF 31/54 reads (57%) | catalogued as rs1237658988, COSV100919319; called by muse, mutect2, varscan2
- NODAL | c.834C>T p.G278= | Silent (SNP) | VAF 40/87 reads (46%) | catalogued as rs1564667124, COSV54661063; called by muse, mutect2, varscan2
- OR5M10 | c.606T>C p.V202= | Silent (SNP) | VAF 34/243 reads (14%) | catalogued as COSV101595886; called by muse, mutect2, varscan2
- PALMD | c.480T>C p.N160= | Silent (SNP) | VAF 78/344 reads (23%) | catalogued as COSV99586381; called by muse, mutect2, varscan2
- PCLO | c.9708G>A p.E3236= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs777347173, COSV100432919; called by muse, mutect2, varscan2
- PPP1CA | c.792G>A p.V264= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV100334957; called by muse, mutect2, varscan2
- PSEN1 | c.223T>C p.L75= | Silent (SNP) | VAF 57/168 reads (34%) | catalogued as rs1478565878, COSV99997842; called by muse, mutect2, varscan2
- PYHIN1 | c.531A>G p.P177= | Silent (SNP) | VAF 49/231 reads (21%) | catalogued as COSV100932354; called by muse, mutect2, varscan2
- SLC2A2 | c.546C>T p.T182= | Silent (SNP) | VAF 22/124 reads (18%) | catalogued as rs773878999, COSV100049336; called by muse, mutect2, varscan2
- VPS13A | c.7749A>G p.E2583= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV100652835; called by muse, mutect2, varscan2
- CLCA3P | n.658T>C | RNA (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
